Surgical pathology report (de-identified scan), TCGA case TCGA-TK-A8OK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Global BioClinical - Georgia, specimen TCGA-TK-A8OK-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, NOS 8140/3
Site: Prostate NOS C61.9

9/5/30/14

DEPARTMENT OF PATHOLOGY

Patient:

received:

Sent out:

Sex: male

Date of birth:

Clinical diagnosis: prostate cancer

Macroscopy: prostate 5x4x4 cm with yellowish foci in both lobes. 3 lymph nodes.

Microscopy: the prostate tumor with gland and some cribriform structures formation. The gland lined by single layer of cells, with perineural invasion and angiolymphatic invasion.

The tumor confined to prostate without extraprostatic extension.

Gleason score 7=4+3.

Metastasis in 1 lymph node out of 3.

Conclusion: Prostate adenocarcinoma, Gleason score 7. pT2N1. ICD-O code M8140/3.

Head of pathology department

Pathologist:

ICD-O Discrepancy		✓
Out-of-Synchrony Primary		✓

Source: NCI Genomic Data Commons file 8c484315-e8c2-49b4-a192-ee3eb5ab2c1d (TCGA-TK-A8OK.887947BA-A888-40C4-8582-EE89E678EC04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).